Gene-level copy-number profile of tumor specimen ALCH-B465-TTP1-A from ALCHEMIST case ALCH-B465, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.8 years (29,528 days).
Specimen ALCH-B465-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 48d490b2-be3f-4d6c-9ce3-31ad54744a5f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B465-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/48d781ca-c7c5-4e63-b6e7-2e73b2988013

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 2,925; copy number 2: 54,127; copy number 3: 714; copy number 4: 272; copy number 5: 166; copy number 6: 5; copy number 7: 22; copy number 8: 11; copy number 9: 1; copy number 10: 59.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,978,926–17,011,928, 3 genes (within-gene range 0–2): AL049569.1, ATP13A2, AL049569.3.
- chr2:127,638,381–127,681,786, 2 genes: LIMS2, GPR17.
- chr2:219,538,948–219,543,809, 1 gene (within-gene range 0–2): CHPF.
- chr3:52,373,652–52,374,882, 1 gene (within-gene range 0–1): PPP2R5CP.
- chr6:35,070,871–35,071,049, 1 gene (within-gene range 0–2): AL138721.1.
- chr7:6,637,318–6,658,279, 1 gene: ZNF316.
- chr7:56,940,341–56,944,353, 1 gene: AC069152.1.
- chr7:129,770,383–129,785,185, 4 genes: MIR182, MIR96, MIR183, AC084864.1.
- chr7:149,776,042–149,833,979, 1 gene: SSPOP.
- chr11:63,985,853–64,001,811, 1 gene (within-gene range 0–2): OTUB1.
- chr11:68,312,591–68,449,275, 1 gene: LRP5.
- chr13:113,008,778–113,010,319, 2 genes (within-gene range 0–1): AL356740.2, AL356740.3.
- chr13:114,107,569–114,108,820, 1 gene (within-gene range 0–1): RASA3-IT1.
- chr14:73,237,497–73,274,640, 4 genes (within-gene range 0–2): PAPLN, AC004846.1, RNU6-419P, AC004846.2.
- chr14:103,094,723–103,149,408, 6 genes: AL161669.1, EXOC3L4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12.
- chr14:105,489,855–105,499,575, 1 gene (within-gene range 0–2): TEDC1.
- chr15:25,169,337–25,225,284, 31 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:41,493,393–41,583,589, 5 genes: ITPKA, LTK, RPAP1, ELOCP2, TYRO3.
- chr15:45,092,650–45,114,172, 1 gene: DUOX2.
- chr16:366,969–387,113, 2 genes (within-gene range 0–2): MRPL28, PGAP6.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.
- chr19:15,353,385–15,379,798, 1 gene (within-gene range 0–2): AKAP8.
- chr20:3,846,799–3,876,123, 1 gene: MAVS.
- chr22:16,486,985–16,527,237, 3 genes: ACTR3BP6, CHEK2P4, AP000547.2.
- chr22:19,018,043–19,018,916, 1 gene (within-gene range 0–1): AC000095.1.
- chr22:19,031,564–19,034,564, 1 gene: CA15P1.
- chr22:19,045,256–19,048,375, 2 genes (within-gene range 0–2): Y_RNA, DGCR11.
- chr22:23,070,519–23,125,032, 1 gene (within-gene range 0–2): GNAZ.
- chr22:30,368,811–30,421,771, 1 gene (within-gene range 0–2): RNF215.
- chr22:41,900,944–41,947,152, 5 genes (within-gene range 0–2): MIR33A, SHISA8, TNFRSF13C, MIR378I, CENPM.
- chr22:45,875,932–45,891,438, 2 genes: BX324167.2, BX324167.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 264 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:62,643,994–66,037,714, 84 genes, copy number 5–6 (broad region; genes not listed).
- chr12:66,116,555–70,443,923, 93 genes, copy number 5–10 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 3 genes, copy number 5–9: CR383658.1, CR383658.2, BNIP3P6.
- chr16:848,525–849,065, 1 gene, copy number 5: AL031008.1.
- chr16:1,826,941–1,890,434, 5 genes, copy number 5 (within-gene range 2–5): FAHD1, MEIOB, AL031722.1, LINC00254, LINC02124.
- chr19:36,259,540–36,489,902, 8 genes, copy number 5 (within-gene range 2–5): LINC00665, AC092296.2, ZFP14, AC092296.1, AC092296.4, ZFP82, AC092296.3, ZNF566.
- chr19:36,510,687–37,855,215, 55 genes, copy number 5: ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1.
- chr21:10,482,738–13,120,807, 11 genes, copy number 5 (within-gene range 3–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:18,906,028–18,947,732, 3 genes, copy number 8 (within-gene range 3–8): DGCR6, AC007326.4, PRODH.
- chr22:20,348,758–20,354,387, 1 gene, copy number 8 (within-gene range 4–8): AC007731.5.

Autosomal genes at a single copy (total copy number 1): 2,907. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
